Gene-level copy-number profile of specimen HCM-SANG-0284-C18-85A from HCMI case HCM-SANG-0284-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0284-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0e853c17-dd7c-4a9e-8d7e-e24f478fd025.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0284-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/52cd9308-a134-4b72-a443-b53190df6407

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 159; copy number 2: 14,828; copy number 3: 31,028; copy number 4: 10,032; copy number 5: 185; copy number 6: 859; copy number 8: 1,297.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,297 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:10,973,336–11,520,175, 4 genes, copy number 8 (within-gene range 5–8): PHF14, RPL23AP52, AC004160.1, NPM1P11.
- chr7:11,406,955–11,414,078, 1 gene, copy number 8 (within-gene range 5–8): AC004160.2.
- chr13:19,345,049–114,337,626, 1,292 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 159. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
